Somatic mutation profile of tumor specimen TCGA-BC-A10T-01A (aliquot TCGA-BC-A10T-01A-11D-A12Z-10) from TCGA case TCGA-BC-A10T, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G1; Age at diagnosis: 76.5 years (27,944 days).
Specimen TCGA-BC-A10T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38b1ffa7-1987-4bb7-a836-550ecf665b41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BC-A10T-11A (Solid Tissue Normal), aliquot TCGA-BC-A10T-11A-11D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4f3fcd9-b647-45ae-b459-58949a09f89c

The open-access MAF lists 81 somatic variants for this specimen: 58 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 22, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 2, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DEPDC5 | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 56/109 reads (51%) | catalogued as rs772872014, CM146220, COSV56694430; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS19 | c.1811A>T p.E604V | Missense Mutation (SNP) | VAF 84/291 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV50805779; called by muse, mutect2, varscan2
- ADAMTSL4 | c.3056C>T p.P1019L | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as COSV55008577; called by muse, mutect2, varscan2
- ADD2 | c.377T>A p.L126Q | Missense Mutation (SNP) | VAF 102/374 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV52472872; called by muse, mutect2, varscan2
- ADGRL4 | c.1337T>C p.I446T | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV66066583; called by muse, mutect2, varscan2
- APPBP2 | c.914G>T p.C305F | Missense Mutation (SNP) | VAF 114/288 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.695); catalogued as COSV50030211; called by muse, mutect2, varscan2
- BRAT1 | c.1439G>A p.S480N | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV61397489; called by muse, mutect2, varscan2
- C12orf50 | c.39G>T p.W13C | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53899368; called by muse, mutect2
- CDC7 | c.523C>A p.H175N | Missense Mutation (SNP) | VAF 147/432 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52312966; called by muse, mutect2, varscan2
- CDH7 | c.1030G>T p.A344S | Missense Mutation (SNP) | VAF 90/230 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV59895995; called by muse, mutect2, varscan2
- CELSR1 | c.1748C>A p.P583H | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV53101107; called by muse, mutect2, varscan2
- CEP83 | c.1708-1G>A p.X570_splice | Splice Site (SNP) | VAF 142/268 reads (53%) | catalogued as COSV60411609; called by muse, mutect2, varscan2
- CFAP69 | c.2629A>G p.T877A | Missense Mutation (SNP) | VAF 151/407 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.894); catalogued as rs1258914975, COSV60188834; called by muse, mutect2, varscan2
- CHRNB3 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.088); catalogued as rs1285336246, COSV51495078, COSV51495562; called by muse, mutect2, varscan2
- COL6A3 | c.6605G>A p.R2202Q | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs768050320, COSV55091677; called by muse, mutect2, varscan2
- CSMD2 | c.3452T>A p.L1151H | Missense Mutation (SNP) | VAF 56/177 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53969169; called by muse, mutect2, varscan2
- CYREN | c.148A>T p.T50S | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as COSV99313323; called by muse, mutect2, varscan2
- ELMO2 | c.1906T>A p.S636T | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV51686514; called by muse, mutect2, varscan2
- EXOC6B | c.1207A>T p.N403Y | Missense Mutation (SNP) | VAF 116/395 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV55574504; called by muse, mutect2, varscan2
- FGGY | c.1568A>G p.D523G | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.062); catalogued as COSV58047024; called by muse, mutect2, varscan2
- HUNK | c.1008C>A p.N336K | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV54235062; called by muse, mutect2, varscan2
- ITGA7 | c.2668-1G>A p.X890_splice (on ENST00000555728; = p.X846_splice on NM_002206.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 20/87 reads (23%) | catalogued as COSV57701982; called by muse, mutect2, varscan2
- KMT2C | c.14735G>T p.*4912Lext*36 | Nonstop Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as COSV51509277; called by muse, mutect2, varscan2
- LAG3 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV52569512; called by muse, mutect2
- LRP1B | c.8596G>A p.D2866N | Missense Mutation (SNP) | VAF 90/267 reads (34%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV67207998; called by muse, mutect2, varscan2
- LRRK1 | c.3529G>A p.D1177N | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV52627571; called by muse, mutect2
- LSM8 | c.114G>T p.L38F | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50800748; called by muse, mutect2, varscan2
- MELK | c.709A>G p.I237V | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV53203199; called by muse, mutect2, varscan2
- MMP19 | c.1388G>T p.R463I | Missense Mutation (SNP) | VAF 266/506 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.254); catalogued as COSV59453524; called by muse, mutect2, varscan2
- NELFCD | c.144T>A p.D48E (on ENST00000602795; = p.D30E on NM_198976.4) | Missense Mutation (SNP) | VAF 59/127 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.042); catalogued as COSV59749374; called by muse, mutect2, varscan2
- NPAP1 | c.3071T>C p.M1024T | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.031); catalogued as COSV61512048; called by muse, mutect2, varscan2
- NT5DC3 | c.379A>G p.I127V | Missense Mutation (SNP) | VAF 266/493 reads (54%) | SIFT tolerated (0.36); PolyPhen benign (0.019); catalogued as COSV67323118; called by muse, mutect2, varscan2
- OPALIN | c.200A>G p.D67G | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); catalogued as rs113141694, COSV64520963; called by muse, mutect2, varscan2
- PAPPA | c.4271G>C p.G1424A | Missense Mutation (SNP) | VAF 94/251 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60292902; called by muse, mutect2, varscan2
- PAX3 | c.22G>T p.V8L | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as COSV51345264; called by muse, mutect2, varscan2
- PDE3A | c.3334T>A p.S1112T | Missense Mutation (SNP) | VAF 82/378 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs986975089, COSV62983726; called by muse, mutect2, varscan2
- PDGFD | c.895G>A p.V299M | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs371743652, COSV56395609; called by muse, mutect2, varscan2
- PHF23 | c.377C>G p.T126S | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as COSV50039969; called by muse, mutect2, varscan2
- POFUT2 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV57961545; called by muse, mutect2, varscan2
- PSD3 | c.247G>C p.A83P | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.046); catalogued as COSV58980662; called by muse, mutect2, varscan2
- RNF213 | c.10778A>G p.Q3593R | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.098); catalogued as COSV60410199; called by muse, mutect2
- SCAPER | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.071); catalogued as COSV57755270; called by muse, mutect2, varscan2
- SDK1 | c.1702C>T p.L568F | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67390494; called by muse, mutect2, varscan2
- SEC24B | c.2831G>A p.R944H | Missense Mutation (SNP) | VAF 17/275 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs759547349, COSV54504583; called by muse, mutect2
- SEMA6D | c.1388G>T p.S463I | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60384921; called by muse, mutect2, varscan2
- SLC39A4 | c.1211T>A p.L404Q (on ENST00000301305 / NM_001374839.1; = p.L379Q on NM_017767.3) | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52781719; called by muse, mutect2, varscan2
- SNX12 | c.304C>G p.L102V | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs778343040, COSV52146713; called by muse, mutect2, varscan2
- SRMS | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs149894938; called by muse, mutect2, varscan2
- SUPT20H | c.1244A>G p.N415S (on ENST00000350612 / NM_001014286.3; = p.N416S on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/244 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs768205505, COSV62249888; called by muse, mutect2, varscan2
- THADA | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 168/273 reads (62%) | catalogued as COSV67093039; called by muse, mutect2, varscan2
- UBE2O | c.3329A>T p.Q1110L | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV60068194; called by muse, mutect2, varscan2
- UNG | c.559T>C p.S187P (on ENST00000242576 / NM_080911.3; = p.S178P on NM_003362.4) | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV54359001; called by muse, mutect2, varscan2
- USP34 | c.10435G>C p.D3479H | Missense Mutation (SNP) | VAF 79/143 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.205); catalogued as COSV63725920; called by muse, mutect2, varscan2
- ZNF518A | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 64/195 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.444); catalogued as COSV60153638; called by muse, mutect2, varscan2
- ZNF532 | c.3757G>A p.E1253K | Missense Mutation (SNP) | VAF 81/216 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as rs772271814, COSV60176148; called by muse, mutect2, varscan2
- ZNHIT6 | c.28A>C p.K10Q | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.014); catalogued as COSV65328184; called by muse, varscan2
- CAMSAP2 | c.1944del p.S649Lfs*24 (on ENST00000236925 / NM_001297707.2; = p.S638Lfs*24 on NM_203459.3) | Frame Shift Del (DEL) | VAF 86/267 reads (32%) | called by mutect2, pindel, varscan2
- OR2B11 | c.208del p.L70Cfs*97 | Frame Shift Del (DEL) | VAF 43/204 reads (21%) | called by mutect2, pindel, varscan2
- ABCB1 | c.1377G>A p.R459= | Silent (SNP) | VAF 41/183 reads (22%) | catalogued as COSV55946537, COSV55964922; called by muse, mutect2, varscan2
- AGAP6 | c.1209G>A p.T403= (on ENST00000374056 / NM_001365867.1; = p.T426= on NM_001077665.2) | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs1264481101, COSV65017878; called by mutect2, varscan2
- ARMCX6 | c.199C>A p.R67= | Silent (SNP) | VAF 89/107 reads (83%) | catalogued as COSV100726220, COSV62680988; called by muse, mutect2, varscan2
- BPTF | c.2583T>G p.A861= | Silent (SNP) | VAF 297/765 reads (39%) | catalogued as COSV58848159; called by muse, mutect2, varscan2
- CABP4 | c.336C>T p.Y112= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs369080675; called by muse, varscan2
- CCNJL | c.834G>A p.R278= | Silent (SNP) | VAF 84/308 reads (27%) | catalogued as COSV57447305; called by muse, mutect2, varscan2
- CYP4A22 | c.111C>A p.L37= | Silent (SNP) | VAF 50/184 reads (27%) | catalogued as COSV53742738; called by muse, mutect2, varscan2
- CYREN | c.147G>T p.A49= | Silent (SNP) | VAF 41/113 reads (36%) | catalogued as COSV51965839, COSV99313324; called by muse, mutect2, varscan2
- DGKA | c.393C>T p.D131= | Silent (SNP) | VAF 95/378 reads (25%) | catalogued as COSV59388977; called by muse, mutect2, varscan2
- EPHA6 | c.507A>T p.V169= | Silent (SNP) | VAF 55/155 reads (35%) | catalogued as rs762684823, COSV101066022, COSV67595678; called by muse, mutect2, varscan2
- HPS6 | c.573C>T p.F191= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs1403615998, COSV100154832, COSV54626879; called by muse, mutect2, varscan2
- IL6ST | c.1584A>G p.K528= | Silent (SNP) | VAF 111/350 reads (32%) | catalogued as COSV61143127; called by muse, mutect2, varscan2
- MAPK6 | c.2165A>G p.*722= | Silent (SNP) | VAF 102/256 reads (40%) | catalogued as COSV55931954, COSV99959047; called by muse, mutect2, varscan2
- MFGE8 | c.270T>G p.S90= | Silent (SNP) | VAF 47/166 reads (28%) | catalogued as COSV51558079; called by muse, mutect2, varscan2
- MFSD2B | c.579G>A p.L193= | Silent (SNP) | VAF 23/112 reads (21%) | catalogued as COSV57856436; called by muse, mutect2, varscan2
- MPP7 | c.411A>G p.V137= | Silent (SNP) | VAF 76/206 reads (37%) | catalogued as COSV61738983; called by muse, mutect2, varscan2
- MRPL11 | c.60C>A p.I20= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs754601760, COSV60599644; called by muse, mutect2, varscan2
- SLC8A1 | c.585A>C p.T195= | Silent (SNP) | VAF 88/178 reads (49%) | catalogued as COSV60498063; called by muse, mutect2, varscan2
- SYNE1 | c.10620A>G p.V3540= (on ENST00000367255 / NM_182961.4; = p.V3547= on NM_033071.3) | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as rs1308068026, COSV55041690; called by muse, mutect2, varscan2
- TM4SF18 | c.90C>T p.F30= | Silent (SNP) | VAF 101/349 reads (29%) | catalogued as rs1277474447, COSV56060160; called by muse, mutect2, varscan2
- TMEM127 | c.459C>T p.L153= | Silent (SNP) | VAF 11/127 reads (9%) | catalogued as rs912034638, COSV51499152; called by muse, mutect2
- ZNF572 | c.57G>A p.E19= | Silent (SNP) | VAF 58/257 reads (23%) | catalogued as COSV60002997; called by muse, mutect2, varscan2
- MIR1283-2 | n.28C>T | RNA (SNP) | VAF 90/247 reads (36%) | catalogued as rs971367084; called by muse, mutect2, varscan2
